Somatic mutation profile of tumor specimen TCGA-X7-A8DB-01A (aliquot TCGA-X7-A8DB-01A-11D-A423-09) from TCGA case TCGA-X7-A8DB, project TCGA-THYM (Thymoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Thymoma, type B2, NOS; Tissue or organ of origin: Anterior mediastinum; Age at diagnosis: 71.3 years (26,035 days).
Specimen TCGA-X7-A8DB-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 47f7a5e9-ba68-45b6-8a92-f7de9697023f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-X7-A8DB-10A (Blood Derived Normal), aliquot TCGA-X7-A8DB-10A-01D-A426-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7c531ffd-3a79-4f73-b8af-3afec744ffcb

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Frame Shift Del 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- H1-6 | c.188del p.L63Wfs*15 | Frame Shift Del (DEL) | VAF 4/34 reads (12%) | called by mutect2, pindel
- RNF169 | c.1952del p.P651Qfs*37 | Frame Shift Del (DEL) | VAF 4/32 reads (13%) | called by mutect2, pindel*
- ISM2 | c.1557T>A p.P519= | Silent (SNP) | VAF 3/50 reads (6%) | called by muse, mutect2
